Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3524, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3524-01A (Primary Tumor).

*** Diagnosis / Diagnoses: ***

1.: Resectate of the colon or sigmoid colon with diverticulosis, with tumor-free oral and aboral resection margins and under inclusion of an ulcerated, moderately differentiated adenocarcinoma, with infiltration of the perimuscular fatty tissue and without regional lymph node metastases (G2, pT3 pN0 0/28 L0 V0 R0).

2.: Tubular colonic mucosal adenoma with slight dysplasia (synonym: low-grade intra-epithelial neoplasia).

Source: NCI Genomic Data Commons file cecf0057-8274-4b7d-9d0f-ceb78654c0b2 (TCGA-AA-3524.21A38B39-57BE-4CA0-AD3F-F81463E63A05.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).